MMRF case MMRF_1415 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/33315555-294e-4fd5-8db6-e33ccc5477fe

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Dead; Days to death: 469 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.4 years (18,408 days); ISS stage: III; Days to last known disease status: 469 days (1.3 years); Days to last follow up: 469 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 115 days; Days to treatment end: 115 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 220 days; Days to treatment end: 310 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 310 days; Days to treatment end: 371 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 320 days; Days to treatment end: 371 days (1.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 378 days (1.0 years); Days to treatment end: 381 days (1.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 402 days (1.1 years); Days to treatment end: 463 days (1.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 469.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 1): M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 769 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 5.48 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 10.5 µg/mL; Lactate Dehydrogenase 7.23 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 7.7 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 147 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.03 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 5.5 mmol/L.
- Day 82: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 5.38 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.67 g/L; Beta 2 Microglobulin 1.38 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.83 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.
- Day 179 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 5.74 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.51 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 5.5 mmol/L.
- Day 291 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.58 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.46 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 7.54 mmol/L.
- Day 363 (ECOG 1): M Protein 1.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 211 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.04 mg/dL; Immunoglobulin G 2.81 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 2.92 µg/mL; Hemoglobin 4.53 mmol/L; Leukocytes 1.3 ×10⁹/L; Platelets 5 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.43 mmol/L; Albumin 26 g/L; Total Protein 7.6 g/dL; Glucose 8.09 mmol/L.
- Day 460 (ECOG 2): M Protein 0.95 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 201 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.045 mg/dL; Immunoglobulin G 2.83 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 10 µg/mL; Lactate Dehydrogenase 9.37 µkat/L; Hemoglobin 4.65 mmol/L; Leukocytes 0.9 ×10⁹/L; Absolute Neutrophil 0.33 ×10⁹/L; Platelets 10 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 32 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -3: Weight: 115 kg; Height: 188 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: male.

Biospecimens (1 sample)
- Sample MMRF_1415_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
